Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4306, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4306-01A (Primary Tumor).

Diagnosis:

I) shows liver metastases of a poorly differentiated carcinoma,
in II) there is a lymph node metastasis of a poorly differentiated carcinoma and
in III) gastric resection material showing parts of an invasive of a poorly differentiated carcinoma with infiltration of all parietal layers extending to the serosa and also lymph node metastases.

The immediate resection margins of the material described under III) in the region of the mucosa were tumor-free.

Tumor classification:

ICDO-DA M

8140/3

pT3,

pN2,

L1, V1,

pM1.

Source: NCI Genomic Data Commons file 479edb7e-462a-434c-88c4-795e2d568d41 (TCGA-CG-4306.392A8034-DBC4-4F5C-AB20-0592B43ED398.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).